Somatic mutation profile of tumor specimen ALCH-B3FR-TTP1-A (aliquot ALCH-B3FR-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3FR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.7 years (23,278 days).
Specimen ALCH-B3FR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 025d9189-4a80-47a5-9ad8-fc41e4ab7a94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FR-NB1-A (Blood Derived Normal), aliquot ALCH-B3FR-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34b31217-9d09-4703-ad9c-83418471e023

The open-access MAF lists 150 somatic variants for this specimen: 86 protein-altering or splice-affecting, 46 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 46, Intron 8, Frame Shift Del 4, 3'UTR 4, Nonsense Mutation 3, Splice Region 3, RNA 3, 3'Flank 2, Translation Start Site 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSA | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 48/198 reads (24%) | catalogued as rs398123419, CM065973, BM0393251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HSD3B2 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs80358220, CM023090, COSV65593255; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 101/548 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASS | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 84/437 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.386); catalogued as COSV100741592, COSV62789109; called by muse, mutect2, varscan2
- ABCA13 | c.14884A>G p.N4962D | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs772025951; called by muse, mutect2, varscan2
- AC004076.1 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.08); catalogued as rs1323637749; called by muse, mutect2
- AFM | c.1151G>T p.C384F | Missense Mutation (SNP) | VAF 79/425 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749103535; called by muse, mutect2, varscan2
- ATXN3 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs200118135, COSV100515431; called by muse, mutect2, varscan2
- CDH9 | c.1158del p.S387Lfs*3 | Frame Shift Del (DEL) | VAF 70/401 reads (17%) | catalogued as COSV50555259; called by mutect2, pindel, varscan2
- COL4A1 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 80/362 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.09); catalogued as rs559277622; called by muse, mutect2, varscan2
- DIPK1B | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1304283886; called by muse, mutect2, varscan2
- DNAH8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 107/571 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs750965126, COSV59480326; called by muse, mutect2, varscan2
- DPY19L2 | c.1608G>T p.L536= | Splice Region (SNP) | VAF 63/309 reads (20%) | catalogued as COSV61046954; called by muse, mutect2, varscan2
- DPYSL5 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs752901583, COSV56517091; called by muse, mutect2, varscan2
- ERN2 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.384); catalogued as rs751819262; called by muse, mutect2, varscan2
- FTSJ1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1244838116, COSV50026562; called by muse, mutect2, varscan2
- GRK3 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV60799823; called by muse, mutect2, varscan2
- INTS10 | c.2073G>T p.M691I | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV101208724; called by muse, mutect2, varscan2
- LRP2 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.058); catalogued as rs759114383; called by muse, varscan2
- MAGEL2 | c.3613C>A p.H1205N | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV58568959; called by muse, mutect2, varscan2
- MARCHF4 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56108729; called by muse, mutect2, varscan2
- NEB | c.5061G>A p.W1687* | Nonsense Mutation (SNP) | VAF 28/161 reads (17%) | catalogued as CM1413896; called by muse, mutect2, varscan2
- NRSN1 | c.382A>C p.T128P | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as rs780892047; called by muse, mutect2, varscan2
- PCDH15 | c.5159C>A p.S1720Y (on ENST00000644397 / NM_001354429.2; = p.S1662Y on NM_001142771.2) | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as COSV100905793; called by mutect2, varscan2
- POGZ | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 59/430 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV99652579; called by muse, mutect2, varscan2
- PREX1 | c.1496del p.G499Afs*17 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | catalogued as COSV64253299; called by mutect2, pindel, varscan2
- PRKDC | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs745764246, COSV58052352; called by muse, mutect2, varscan2
- PXDNL | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1049626878, COSV62493530; called by muse, mutect2, varscan2
- RAI2 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV58963726; called by muse, mutect2, varscan2
- RYR2 | c.7234G>T p.G2412W | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772934, COSV63696306; called by mutect2, varscan2
- SLC4A1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52260247; called by muse, mutect2, varscan2
- SNTG1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52445120; called by muse, mutect2, varscan2
- SPANXD | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 102/484 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs781799400; called by muse, mutect2, varscan2
- STOML2 | c.804+8G>T | Splice Region (SNP) | VAF 22/118 reads (19%) | catalogued as rs1422415315; called by muse, mutect2, varscan2
- SYNE1 | c.20158G>T p.E6720* (on ENST00000367255 / NM_182961.4; = p.E6649* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 140/611 reads (23%) | catalogued as COSV99577539; called by muse, mutect2, varscan2
- TKTL2 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54919083; called by muse, mutect2, varscan2
- TRAPPC12 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as rs1341264281; called by muse, mutect2
- ZFC3H1 | c.1304A>T p.Q435L | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV66435381; called by muse, mutect2, varscan2
- ANHX | c.553T>C p.F185L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CCDC54 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD244 | c.1073T>C p.L358S (on ENST00000368033 / NM_001166663.2; = p.L353S on NM_016382.4) | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.9190C>A p.H3064N (on ENST00000297405 / NM_001363185.1; = p.H2895N on NM_052900.3) | Missense Mutation (SNP) | VAF 158/525 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CUBN | c.4582del p.S1528Vfs*23 | Frame Shift Del (DEL) | VAF 78/363 reads (21%) | called by mutect2, pindel, varscan2
- DCX | c.761C>G p.P254R | Missense Mutation (SNP) | VAF 107/553 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DCX | c.760C>G p.P254A | Missense Mutation (SNP) | VAF 109/555 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- DOCK2 | c.3221G>T p.W1074L | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GABRG3 | c.1026C>G p.S342R | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- GAS2L2 | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDPD5 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GRID2 | c.1633G>T p.V545L | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HDAC9 | c.2842G>T p.V948L | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOATZ | c.481G>T p.D161Y (on ENST00000375618 / NM_001100388.1; = p.D188Y on NM_207430.2) | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- HOXC4 | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- HSD3B2 | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- INPP5F | c.2939T>A p.V980E | Missense Mutation (SNP) | VAF 70/351 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ITPR3 | c.1885A>T p.R629W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- KCNQ1 | c.953_954delinsT p.K318Mfs*36 | Frame Shift Del (DEL) | VAF 51/264 reads (19%) | called by pindel, varscan2*
- KEAP1 | c.491T>G p.I164S | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- KIAA0408 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2
- L1CAM | c.2756G>C p.G919A | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- MED12 | c.2278G>A p.V760M | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MINAR1 | c.1754C>A p.T585N | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH10 | c.1189C>A p.L397M | Missense Mutation (SNP) | VAF 84/385 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO5B | c.2688G>T p.M896I | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEGR1 | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- NONO | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR14C36 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- OR6B1 | c.167A>C p.H56P | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- OTOP1 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PENK | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.017); called by muse, varscan2
- POLN | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, varscan2
- PRUNE2 | c.4612A>T p.S1538C | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PTCRA | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- RGS7 | c.1187C>G p.A396G | Missense Mutation (SNP) | VAF 67/411 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- RYR2 | c.8477T>A p.I2826N | Missense Mutation (SNP) | VAF 167/930 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SOBP | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SORCS1 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPACA3 | c.61_63del p.P21del | In Frame Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- THOC2 | c.2203G>T p.D735Y | Missense Mutation (SNP) | VAF 86/413 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- TMEM70 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TRO | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- USP11 | c.2216-4C>A | Splice Region (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- USP26 | c.1939G>T p.A647S | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- UTP18 | c.1581G>T p.M527I | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XAF1 | c.188A>T p.Q63L | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZBED1 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- AC100868.1 | c.987C>A p.L329= | Silent (SNP) | VAF 178/431 reads (41%) | catalogued as COSV51848640; called by muse, mutect2
- ACBD3 | c.207G>T p.A69= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- ANKRD18A | c.2586A>T p.S862= | Silent (SNP) | VAF 36/142 reads (25%) | called by muse, mutect2, varscan2
- APOBEC3A | c.555C>A p.A185= | Silent (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.105G>T p.L35= | Silent (SNP) | VAF 28/203 reads (14%) | called by muse, mutect2, varscan2
- ATP2A1 | c.2211C>T p.D737= | Silent (SNP) | VAF 62/254 reads (24%) | catalogued as rs747911513; called by muse, mutect2, varscan2
- BOD1L2 | c.66C>T p.G22= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV101649294; called by muse, mutect2, varscan2
- C6orf15 | c.261C>T p.F87= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- CASS4 | c.306T>A p.T102= | Silent (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- CCDC136 | c.834G>C p.T278= | Silent (SNP) | VAF 50/219 reads (23%) | catalogued as COSV52803078; called by muse, mutect2, varscan2
- CHSY3 | c.2217A>G p.Q739= | Silent (SNP) | VAF 66/379 reads (17%) | called by muse, mutect2, varscan2
- CNNM1 | c.2430G>T p.G810= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.954C>T p.G318= | Silent (SNP) | VAF 77/479 reads (16%) | catalogued as rs1470469267; called by muse, mutect2, varscan2
- COL6A3 | c.7098C>T p.P2366= | Silent (SNP) | VAF 130/538 reads (24%) | called by muse, mutect2, varscan2
- DPEP3 | c.195T>A p.T65= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- EPOP | c.1047C>A p.P349= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- EYS | c.1245C>A p.L415= | Silent (SNP) | VAF 84/531 reads (16%) | called by muse, mutect2, varscan2
- GRIK2 | c.1173G>T p.V391= | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as COSV59759221; called by muse, mutect2, varscan2
- KBTBD3 | c.102T>C p.H34= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs753809738; called by muse, mutect2, varscan2
- LIF | c.597C>G p.A199= | Silent (SNP) | VAF 36/183 reads (20%) | called by muse, mutect2, varscan2
- LRP1B | c.8838G>T p.P2946= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV101260549, COSV67214609; called by muse, mutect2, varscan2
- LRRC9 | c.3780C>A p.I1260= | Silent (SNP) | VAF 50/284 reads (18%) | called by muse, mutect2, varscan2
- MLC1 | c.858C>A p.I286= | Silent (SNP) | VAF 64/336 reads (19%) | catalogued as rs140824687; called by muse, mutect2, varscan2
- MORC4 | c.1674A>G p.L558= | Silent (SNP) | VAF 80/382 reads (21%) | catalogued as rs1437350765; called by muse, mutect2, varscan2
- MYH3 | c.1824G>T p.G608= | Silent (SNP) | VAF 50/262 reads (19%) | called by muse, mutect2, varscan2
- NHS | c.3459C>T p.A1153= | Silent (SNP) | VAF 132/710 reads (19%) | catalogued as CD033211; called by muse, mutect2, varscan2
- NTRK3 | c.984C>T p.N328= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as rs754732972, COSV58142753; called by muse, mutect2, varscan2
- OR2AT4 | c.729C>T p.F243= | Silent (SNP) | VAF 32/166 reads (19%) | called by muse, mutect2, varscan2
- OR4K1 | c.687C>T p.S229= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99578516; called by muse, mutect2, varscan2
- OR6B3 | c.747C>T p.T249= | Silent (SNP) | VAF 59/243 reads (24%) | catalogued as rs376012671; called by muse, mutect2, varscan2
- P3H4 | c.927G>T p.V309= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1611G>T p.A537= | Silent (SNP) | VAF 71/404 reads (18%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.1002T>C p.N334= | Silent (SNP) | VAF 71/296 reads (24%) | catalogued as COSV65049156; called by muse, mutect2, varscan2
- PRR12 | c.108T>C p.H36= (on ENST00000615927; = p.H857= on NM_020719.3) | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1423286785; called by muse, mutect2, varscan2
- PRR23C | c.219G>T p.L73= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2691G>A p.G897= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV55485330; called by muse, mutect2, varscan2
- RNF128 | c.135G>T p.A45= | Silent (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- RNF31 | c.981A>T p.R327= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as COSV53758352; called by muse, mutect2, varscan2
- SDCCAG8 | c.957A>T p.L319= | Silent (SNP) | VAF 112/731 reads (15%) | called by muse, mutect2, varscan2
- SLC18A3 | c.813G>T p.R271= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- TBC1D8 | c.2532C>T p.H844= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs374565153; called by muse, mutect2, varscan2
- TBX2 | c.2037C>A p.G679= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- TCP11X2 | c.774G>T p.P258= | Silent (SNP) | VAF 106/763 reads (14%) | called by muse, mutect2, varscan2
- TRAF4 | c.756C>T p.F252= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.48402A>G p.V16134= (on ENST00000591111; = p.V8710= on NM_003319.4) | Silent (SNP) | VAF 54/281 reads (19%) | called by muse, mutect2, varscan2
- TUBA3D | c.361C>A p.R121= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV58310979, COSV58313237; called by mutect2, varscan2
- BOD1P2 | n.430C>G | RNA (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65782C>A | Intron (SNP) | VAF 40/147 reads (27%) | catalogued as COSV54666674; called by muse, mutect2, varscan2
- EIF3E | c.471+1356C>T | Intron (SNP) | VAF 24/119 reads (20%) | called by muse, varscan2
- FAS | c.*1458A>T | 3'UTR (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2
- GTF2A1 | c.-25C>T | 5'UTR (SNP) | VAF 65/210 reads (31%) | catalogued as rs1403985491; called by muse, mutect2, varscan2
- KDM8 | c.-32+457A>G | Intron (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- LINC01567 | n.400A>T | RNA (SNP) | VAF 37/155 reads (24%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-10700A>T | Intron (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156440 C>G | 3'Flank (SNP) | VAF 54/252 reads (21%) | called by muse, mutect2, varscan2
- PEX7 | c.*34G>T | 3'UTR (SNP) | VAF 108/487 reads (22%) | called by muse, mutect2, varscan2
- PIN1 | c.*82C>T | 3'UTR (SNP) | VAF 4/35 reads (11%) | catalogued as rs549785418; called by mutect2, varscan2
- SEPTIN6 | c.690+3118G>A | Intron (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- SPINT2 | c.554-9C>G | Intron (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- TRIM37 | c.860+28T>C | Intron (SNP) | VAF 57/298 reads (19%) | called by muse, mutect2, varscan2
- XYLT2 | chr17:50363010 T>C | 3'Flank (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- ZDHHC9 | c.*6C>A | 3'UTR (SNP) | VAF 94/463 reads (20%) | catalogued as COSV64096357; called by muse, mutect2, varscan2
- ZNF542P | n.964G>A | RNA (SNP) | VAF 30/134 reads (22%) | catalogued as rs753660826; called by muse, varscan2
- ZNF606 | c.-52+45T>A | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
